Somatic mutation profile of tumor specimen TCGA-EL-A3CV-01A (aliquot TCGA-EL-A3CV-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 40.5 years (14,785 days).
Specimen TCGA-EL-A3CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d9dcd7-f85d-45e1-a196-c34954f4e0bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CV-10A (Blood Derived Normal), aliquot TCGA-EL-A3CV-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7db0b07a-742c-4512-9f1f-d8080e0f4eb4

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by mutect2, varscan2
- CNR1 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV62990852; called by muse, mutect2, varscan2
- PTCD2 | c.778A>G p.I260V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as rs765626476, COSV57339015; called by muse, mutect2, varscan2
- SCN3A | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1304665415, COSV51821989, COSV51824418; called by muse, mutect2, varscan2
- TRANK1 | c.8030G>A p.R2677Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs779627377, COSV57162282; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52854256; called by muse, mutect2, varscan2
- ZBTB24 | c.2073A>T p.P691= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV57783169; called by muse, mutect2, varscan2
